Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7820, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7820-01A (Primary Tumor).

[page 1 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

PROSTATE, RADICAL PROSTATECTOMY:

- PROSTATE ADENOCARCINOMA, GLEASON SCORE 3+4=7.
- MULTIFOCAL, LARGEST FOCUS 1.3 CM.
- INVOLVES RIGHT AND LEFT PROSTATE LOBES.
- NO EXTRAPROSTATIC EXTENSION IDENTIFIED.
- SURGICAL MARGINS FREE OF TUMOR.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade: Prostatic adenocarcinoma, Gleason score 3+4=7.

Primary tumor: pT2c.

Regional lymph node: pNX.

Distant metastasis: pMX.

Pathologic stage: IIB.

Perineural invasion: Not identified.

Lymphovascular invasion: Not identified.

Surgical margins: R0, negative.

[page 2 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Prostate Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, [REDACTED])

Procedure:	Radical prostatectomy.
Specimen type:	Prostate.
Prostate site/weight:	42 grams, 5.1 x 3.4 x 3.2 cm.
TUMOR FEATURES:	
Tumor site:	Right and left prostate.
Tumor size:	Multifocal, largest focus 1.3 cm.
Tumor quantification:	5% of prostate.
Histologic type:	Prostatic adenocarcinoma.
Histologic grade (Gleason pattern):	
Primary pattern:	3.
Secondary pattern:	4.
Tertiary pattern:	N/A.
Total Gleason score:	7.
Lymphovascular invasion:	Not identified.
Perineural invasion:	Not identified.
Extraprostatic extension:	Not identified.
Seminal vesicle invasion:	Not identified.
Treatment effect:	N/A.
LYMPH NODES:	N/A.
MARGIN EVALUATION:	
Distance to closest margin:	0.1 cm from left apex and posterior margin.
Other margins:	0.2 cm from right apex.
PATHOLOGIC TUMOR STAGING DESCRIPTORS:	
Primary tumor:	pT2c.
Regional lymph node:	pNX.
Distant metastasis:	pMX.
Margin status:	R0, negative.
Pathologic stage:	IIB.
Additional findings:	High grade prostatic intraepithelial neoplasia.
Comment:	N/A.

[page 3 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:
Prostatectomy

Gross Description:
Specimen is designated as prostate. Initially received in the fresh state for tumor bank study is a 42 gram radical prostatectomy, 5.1 cm apex to base, 3.4 cm across and 3.2 cm posterior-anterior. The attached right seminal vesicle extends up to 2.7 x 1.4 x 0.5 cm, adjacent vas 1.4 x 0.4 cm: the left seminal vesicle extends up to 3.0 x 1.4 x 0.5 cm and corresponding vas 1.9 x 0.4 cm. The prostate margin has a shaggy, pink and tan appearance and the margins are now differentially inked as follows: posterior - black, right body prostate - blue and remaining left body prostate green. Sectioning through the bilateral seminal vesicles demonstrate rubbery honeycomb, pink and tan cut surface without gross tumor involvement. The prostate is serially sectioned, apex to base, demonstrating a variegated rubbery, mildly congested, pink and yellow-tan cut surface with circumscribed nodularity predominating the anterior half of the specimen against the urethral tract. A suspicious focus of glistening deep yellow change is appreciated near the left apical and posterior margins upwards of 1.0 x 0.9 x 0.8 cm. Representative portion of this suspicious lesion is submitted for tumor bank. Further examination of the cut sections of prostate demonstrate additional foci of suspicious yellow-orange change posterior to the urethral tract near the base, upwards of 0.5 cm, and the origin of the right seminal vesicles demonstrates an additional 0.5 cm focus of suspicion for malignancy. Tissue included within the container are two oriented tubular fragments of apparent vas deferens, 2.3 x 0.5 cm and 2.5 x 0.4 cm each. Representative sections are submitted for microscopic evaluation.

Cassette summary: A1) unoriented vas deferens segments represented, A2) right and left vas margins and seminal vesicles represented, A3-A4) right and left apex sections submitted, respectively, A5-A6) right and left base sections submitted, respectively, A7-A11) representation of right body of prostate, apex towards base, A12-A18) representation left body of prostate, apex towards base.

Microscopic Description:
Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file bf4487fd-6fc7-4829-afb8-fb2ce1d880a6 (TCGA-HC-7820.750C91EB-1732-4CA3-8C71-F1309A90E4F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).